Surgical pathology report (de-identified scan), TCGA case TCGA-23-1107, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1107-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

PATIENT: [REDACTED]

PATH #: [REDACTED]

Hospital No.: [REDACTED]

Date of Birth: [REDACTED]

Soc. Sec. No.: [REDACTED]

Location: [REDACTED]

A/S: [REDACTED]

Rec: [REDACTED]

Pathologist: [REDACTED]

Assistant: [REDACTED]

Attending MD: [REDACTED]

Ordering MD: [REDACTED]

Copies To: [REDACTED]

DIAGNOSIS:

1. OMENTUM, BIOPSIES:
- Metastatic moderately to poorly differentiated papillary adenocarcinoma, consistent with origin in ovary
2. OMENTUM:
- Omentum diffusely infiltrated by papillary adenocarcinoma
3. LEFT OVARY, RESECTION:
- Ovary almost completely replaced by moderately to poorly differentiated papillary adenocarcinoma
4. RIGHT OVARY AND FALLOPIAN TUBE, RESECTION:
- Ovary almost completely replaced by moderately to poorly differentiated papillary adenocarcinoma
- Fallopian tube shows multifocal severe dysplasia and intraepithelial carcinoma, with a focal intraluminal mass of poorly differentiated carcinoma
- The remainder of the fallopian tube is unremarkable
5. BLADDER TUMOR, BIOPSY:
- Fibroconnective and fibrofatty tissue almost completely replaced by papillary adenocarcinoma
6. CUL-DE-SAC TUMOR, BIOPSY:
- Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
7. CUL-DE-SAC TUMOR, BIOPSY:
- Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
8. PELVIC TUMOR, BIOPSY:
- Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
9. RIGHT PERIAORTIC TUMOR, BIOPSY:
- Fibroconnective tissue almost completely replaced by papillary adenocarcinoma

[page 2 of 6]
10. RECTOSIGMOID TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
11. RECTOSIGMOID TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
12. CUL-DE-SAC TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
13. SIGMOID MESENTERY, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
14. TRANSVERSE COLON, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
15. LEFT GUTTER TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
-A hemorrhagic cyst is also present
16. SPLEEN, RESECTION:
-Spleen showing multiple capsular metastases of papillary adenocarcinoma
-The spleen parenchyma is unremarkable
17. LIVER, BIOPSY:
-Fibroconnective and fibrofatty tissue almost completely replaced by papillary adenocarcinoma
-Liver is not identified
18. DIAPHRAGM TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
-Attached striated muscle is not infiltrated
19. RIGHT GUTTER TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
20. TRANSVERSE COLON TUMOR, BIOPSY:
-Fibroconnective tissue extensively infiltrated by papillary adenocarcinoma
21. MESENTERIC TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
22. DIAPHRAGM TUMOR, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma
-Diaphragm muscle is not identified
23. SMALL BOWEL MESENTERY, BIOPSY:
-Fibroconnective tissue almost completely replaced by papillary adenocarcinoma

STAGING INFORMATION:

[page 3 of 6]
HISTORY: Ovarian carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: OMENTUM AND FROZEN SECTION OF NO.1

Labeled "omentum and FS#1", received fresh in the Operating Room for frozen section diagnosis and subsequently fixed in formalin, are three tan papillary friable fragments of tumor, 1.5, 2.0, and 2.5 cm in greatest dimension. Representative sections are submitted.

- A. Frozen section remnant - 1
- B. Formalin-fixed tissue - 2

2: OMENTUM

Labeled "omentum" and received in formalin is a previously incised 35 x 18 x 3.5 cm portion of omentum containing at least three large tan papillary masses measuring 7 x 7 x 3 cm, 10 x 6 x 4 cm, and 15 x 9 x 3.5 cm.

- C. Representative sections - 2

3: LEFT OVARY

Labeled "left ovary" and received in formalin is a 5.0 x 5.0 x 1.9 cm ovary. The ovarian stroma has been replaced by soft tan papillary tumor. A fallopian tube is not identified. A representative section is submitted.

- D. Ovary with adjacent tumor - 1

4: RIGHT OVARY AND FALLOPIAN TUBE

Labeled "right ovary and fallopian tube" and received in formalin is a 10.6 x 8.3 x 3.4 cm specimen consisting of a partially cystic and solid, tan, papillary tumor that is replacing any recognizable ovarian stroma. Also identified is a 5.5 x 0.6 cm segment of fallopian tube with fimbria whose fimbriated end appears to be directly adjacent to a 2.0 x 1.5 x 0.9 cm tumor nodule. Representative sections are submitted.

- E. Ovarian tumor - 1
- F. Fimbriated fallopian tube with adjacent tumor nodule and cross section through fallopian tube - 2

5: BLADDER TUMOR

Labeled "bladder tumor" and received in formalin is a 15.0 x 8.6 x 3.5 cm specimen of bladder wall with one surface completely replaced by tan friable papillary tumor.

- G. Representative sections - 2

6: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin are two tan papillary tumor masses, 5.1 x 2.7 x 1.8 cm and 4.8 x 4.5 x 1.5 cm.

- H. Representative sections - 2

7: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin are two tan-red friable papillary fragments of tumor, 2.0 x 1.6 x 0.8 cm and 3.2 x 3.0 x 1.7 cm.

- I. Representative sections - 2

8: PELVIC TUMOR

[page 4 of 6]
[REDACTED]

Labeled "pelvic tumor" and received in formalin is a 7.0 x 4.0 x 1.2 cm fragment of omentum with attached tan-white papillary tumor nodule. The tumor nodule measures 3.5 x 3.0 x 0.9 cm.

J. Representative section - 1

9: RIGHT PERIAORTIC TUMOR

Labeled "right periaortic tumor" and received in formalin is a 9.5 x 4.5 x 3.5 cm irregular tan-red multiloculated cystic and solid, papillary tumor.

K. Representative section - 1

10: RECTOSIGMOID TUMOR

Labeled "rectosigmoid tumor" and received in formalin is an 8.0 x 7.0 x 1.9 cm multiloculated solid and cystic papillary tumor.

L. Representative sections - 2

11: RECTOSIGMOID TUMOR

Labeled "rectosigmoid tumor" and received in formalin are three tan papillary irregular fragments of tumor, 1.8, 2.3, and 3.1 cm in greatest dimension.

M. Representative sections - 2

12: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin is an 11.0 x 10.0 x 3.5 cm aggregate of tan papillary tumor fragments ranging from 2.0 x 1.9 x 1.0 cm to 14.1 x 6.5 x 1.5 cm.

N. Representative sections - 2

13: SIGMOID MESENTERY

Labeled "sigmoid mesentery" and received in formalin is a 2.3 x 1.8 x 1.2 cm tan papillary tumor nodule

O. Representative section - 1

14: TRANSVERSE COLON

Labeled "transverse colon" and received in formalin is a 7.0 x 2.0 x 1.3 cm tan irregular fragment of papillary tumor.

P. Representative section - 1

15: LEFT GUTTER TUMOR

Labeled "left gutter tumor" and received in formalin is a 5.4 x 2.4 x 2.4 cm tan irregular papillary tumor with a small amount of associated colonic fat.

Q. Representative section - 1

16: SPLEEN

Labeled "spleen" and received of photography is a 290 gram specimen consisting of an 11.7 x 6.8 x 3.9 cm spleen and attached perihilar fat measuring 15.0 x 8.5 x 4.5 cm. Within the hilar fat are numerous tan papillary tumor nodules aggregating 7.0 x 6.0 x 3.0 cm and attached to the splenic capsule. Cross sectioning parallel to the hilum of the spleen demonstrates a tan, papillary, 7.5 x 7.5 x 1.7 cm tumor mass on the surface and infiltrating the capsule of spleen. The splenic capsule is also studded with at least four 0.5 to 1.0 cm tumor nodules.

R. Representative section - 1

[page 5 of 6]
[REDACTED]

17: LIVER

Labeled "liver" and received in formalin are two tan 3.5 x 2.5 x 1.8 cm and 6.2 x 3.8 x 1.3 cm fragments of tan papillary tumor.

S. Representative sections - 2

18: DIAPHRAGM TUMOR

Labeled "diaphragm tumor" and received in formalin are two tan-pink fragments of papillary tumor, 3.0 x 2.1 x 1.3 cm and 10.8 x 8.8 x 1.0 cm.

T. Representative sections - 2

19: RIGHT GUTTER TUMOR

Labeled "right gutter tumor" and received in formalin is a 7.0 x 6.0 x 3.5 cm aggregate of hemorrhagic tan papillary tumor ranging from 3.0 x 2.8 x 1.5 cm to 6.8 x 3.0 x 1.8 cm.

U. Representative section - 1

20: TRANSVERSE COLON TUMOR

Labeled "transverse colon tumor" and received in formalin are two tan-red hemorrhagic papillary tumor nodules, 1.6 and 2.4 cm in greatest dimension.

V. Representative sections - 2

21: MESENTERIC TUMOR

Labeled "mesenteric tumor" and received in formalin is a tan-red hemorrhagic, papillary tumor nodule, 2.0 x 1.0 x 0.9 cm. The specimen is all embedded.

W. Tumor nodule, bisected - 1

22: DIAPHRAGM TUMOR

Labeled "diaphragm tumor" and received in formalin is a 10.6 x 4.3 x 1.2 cm fragment of tan papillary tumor.

X. Representative sections - 2

23: SMALL BOWEL MESENTERY

Labeled "small bowel mesentery" and received in formalin are two tan soft papillary tumor nodules measuring 1.4 and 1.5 cm in greatest dimension.

Y. Representative sections - 2

[REDACTED]

OPERATIVE CONSULT (FROZEN):

FS1: High grade mullerian carcinoma

Tumor submitted for clonogenic assay

[REDACTED]

Special Studies: Frozen Section

See Also: None

[REDACTED]

[page 6 of 6]
Confidentiality Warning: The information in this system should only be viewed by physicians and other patient care personnel with a "need to know" for purposes of diagnosis and treatment. All accesses are logged with your name, the patient's name, the type of data viewed, the date and time. Inappropriate accesses are subject to disciplinary measures and/or legal action, up to and including termination of employment on the first offense.

This viewing system is not the official medical record. Any printouts from this system should be disposed of properly and should not be filed or placed in a patient chart.

Source: NCI Genomic Data Commons file 90f4c046-5e9b-4541-a512-a095a637fb53 (TCGA-23-1107.700802E6-8058-4485-8210-3E5B8F10BBF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).